Somatic mutation profile of tumor specimen TCGA-CJ-5683-01A (aliquot TCGA-CJ-5683-01A-11D-1534-10) from TCGA case TCGA-CJ-5683, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 78.7 years (28,745 days).
Specimen TCGA-CJ-5683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d42a6376-0c64-4594-9732-f5e3dcdcd375.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-5683-11A (Solid Tissue Normal), aliquot TCGA-CJ-5683-11A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8e4f7f7-602c-49af-ba13-f16a20ef4177

The open-access MAF lists 69 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 18, Frame Shift Del 5, Intron 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 112/450 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs724159992, CM101236, COSV51621049; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 137/518 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs371889197; called by muse, mutect2, varscan2
- AKAP9 | c.7930A>T p.T2644S (on ENST00000359028; = p.T2620S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/503 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62340659; called by muse, mutect2, varscan2
- CCDC126 | c.25A>C p.N9H | Missense Mutation (SNP) | VAF 158/536 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.33); catalogued as COSV56739298; called by muse, mutect2, varscan2
- CDK3 | c.644T>A p.I215N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56908393; called by muse, mutect2, varscan2
- CDK3 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56908397; called by muse, mutect2, varscan2
- CLPB | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53627931; called by muse, mutect2
- CNST | c.658C>A p.H220N | Missense Mutation (SNP) | VAF 112/375 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63619910; called by muse, mutect2, varscan2
- CTAGE6 | c.1038C>G p.D346E | Missense Mutation (SNP) | VAF 94/740 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.498); catalogued as COSV69916825; called by muse, varscan2
- DCC | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 120/353 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454486031, COSV59089457; called by muse, mutect2, varscan2
- DPAGT1 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 111/312 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53827774; called by muse, mutect2, varscan2
- FBXO3 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 210/725 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV55765246; called by mutect2, varscan2
- FBXO30 | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 162/450 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs755807101, COSV52790425; called by muse, mutect2, varscan2
- GPSM2 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV51441443; called by muse, mutect2, varscan2
- GRIN2B | c.3102G>T p.Q1034H | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as COSV74205055; called by muse, mutect2
- HTR1E | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs61735411, COSV59507076; called by muse, mutect2, varscan2
- HYDIN | c.12352T>A p.F4118I | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66637731; called by muse, mutect2, varscan2
- KMT2C | c.7043A>G p.Q2348R | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV51386328; called by muse, mutect2, varscan2
- KRT13 | c.859A>G p.R287G | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV55839198; called by muse, mutect2, varscan2
- LRP5 | c.2861C>A p.S954Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV53712330; called by mutect2, varscan2
- MAGI3 | c.2289A>T p.K763N | Missense Mutation (SNP) | VAF 130/394 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56829903; called by muse, mutect2, varscan2
- MAX | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52415583; called by muse, mutect2, varscan2
- METTL17 | c.575T>G p.F192C | Missense Mutation (SNP) | VAF 151/569 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59555260; called by muse, mutect2, varscan2
- MFSD14A | c.8A>T p.Q3L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV64514416; called by muse, mutect2, varscan2
- MYH1 | c.4996C>T p.R1666W | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773071362, COSV56844808; called by muse, mutect2
- NAA16 | c.1131G>C p.Q377H | Missense Mutation (SNP) | VAF 154/526 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.315); catalogued as COSV65064474; called by muse, mutect2, varscan2
- NOM1 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 180/824 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.066); catalogued as COSV51979154; called by muse, mutect2, varscan2
- PAPSS1 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 149/491 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV54487179, COSV54487602; called by muse, mutect2, varscan2
- PCDH15 | c.2704T>A p.Y902N | Missense Mutation (SNP) | VAF 182/490 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.348); catalogued as COSV57271528; called by muse, mutect2, varscan2
- PDK2 | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV50303338; called by muse, mutect2, varscan2
- PDPR | c.2036T>C p.L679P | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55349780; called by muse, mutect2
- RBAK | c.1972A>G p.K658E | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV62330910; called by muse, mutect2, varscan2
- RPGRIP1L | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 209/850 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100046419; called by muse, mutect2, varscan2
- RYR3 | c.944C>G p.S315C | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV66780797; called by muse, mutect2, varscan2
- SDE2 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55250209, COSV55251711; called by muse, mutect2, varscan2
- SDK1 | c.5074G>A p.V1692M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as rs754877724, COSV101270039, COSV67359442; called by muse, mutect2, varscan2
- SLC47A2 | c.871T>C p.F291L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV57626814; called by muse, mutect2, varscan2
- TCP11 | c.1327C>T p.Q443* (on ENST00000512012; = p.Q381* on NM_018679.5) | Nonsense Mutation (SNP) | VAF 62/203 reads (31%) | catalogued as COSV55132474; called by muse, mutect2, varscan2
- TDP1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV59642435; called by muse, mutect2, varscan2
- TNFAIP6 | c.123A>C p.E41D | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.992); catalogued as COSV54640140; called by muse, mutect2
- TPH1 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 141/527 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV51457219; called by muse, mutect2, varscan2
- UGT1A4 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59384169; called by muse, mutect2, varscan2
- USP2 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV52727891; called by muse, mutect2, varscan2
- CACNA1A | c.4638_4639del p.L1547Dfs*51 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel
- DENND4C | c.1421del p.Y474Ffs*30 | Frame Shift Del (DEL) | VAF 191/670 reads (29%) | called by mutect2, pindel, varscan2
- EEA1 | c.4001del p.N1334Tfs*12 | Frame Shift Del (DEL) | VAF 279/951 reads (29%) | called by mutect2, pindel, varscan2
- GPR156 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- KRT82 | c.679_681del p.K227del | In Frame Del (DEL) | VAF 50/151 reads (33%) | called by pindel, varscan2
- PBRM1 | c.5059del p.E1687Kfs*? (on ENST00000296302 / NM_001366071.2; = p.E1580Kfs*67 on NM_018313.5) | Frame Shift Del (DEL) | VAF 98/256 reads (38%) | called by mutect2, pindel, varscan2
- PRPF39 | c.933_954del p.H311Qfs*28 | Frame Shift Del (DEL) | VAF 118/528 reads (22%) | called by mutect2, pindel, varscan2
- AZGP1 | c.21C>A p.V7= | Silent (SNP) | VAF 55/264 reads (21%) | catalogued as COSV52797217; called by muse, mutect2, varscan2
- BAHCC1 | c.5871G>A p.E1957= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV57023852; called by muse, mutect2, varscan2
- C19orf12 | c.222C>A p.A74= (on ENST00000392278 / NM_001031726.3; = p.A63= on NM_031448.6) | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV60364280; called by muse, mutect2, varscan2
- FBN3 | c.5275C>T p.L1759= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs761721387, COSV54455121; called by muse, mutect2, varscan2
- FDPS | c.156A>G p.Q52= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV63113972; called by muse, mutect2, varscan2
- LRP1 | c.1221C>T p.G407= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs1333583420, COSV54504191; called by muse, mutect2, varscan2
- LRP2 | c.11460C>T p.S3820= | Silent (SNP) | VAF 96/292 reads (33%) | catalogued as rs371738642; called by muse, mutect2, varscan2
- MIGA1 | c.159T>C p.F53= | Silent (SNP) | VAF 193/618 reads (31%) | catalogued as COSV66222995; called by muse, mutect2, varscan2
- MOGAT2 | c.441G>T p.R147= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as COSV52218671; called by muse, mutect2, varscan2
- MTMR7 | c.1824C>T p.D608= | Silent (SNP) | VAF 107/349 reads (31%) | catalogued as COSV51663766; called by muse, mutect2, varscan2
- MUC13 | c.900G>A p.K300= | Silent (SNP) | VAF 183/654 reads (28%) | catalogued as COSV60698787; called by muse, mutect2, varscan2
- MYO5A | c.255G>C p.V85= | Silent (SNP) | VAF 32/414 reads (8%) | catalogued as COSV62557522; called by muse, mutect2
- OBSCN | c.2046G>C p.L682= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV52749296; called by muse, mutect2, varscan2
- RASA3 | c.1200C>A p.I400= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV61864713, COSV61866788; called by muse, mutect2, varscan2
- RNASEL | c.1584C>T p.V528= | Silent (SNP) | VAF 56/158 reads (35%) | catalogued as COSV62376353; called by muse, mutect2, varscan2
- SLC23A2 | c.1656C>T p.V552= | Silent (SNP) | VAF 78/271 reads (29%) | catalogued as rs368342772; called by muse, mutect2, varscan2
- SLC35A4 | c.99T>C p.H33= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV60051718; called by muse, mutect2
- TMEM132B | c.249T>C p.I83= | Silent (SNP) | VAF 77/248 reads (31%) | catalogued as COSV54747095; called by muse, mutect2, varscan2
- NFASC | c.2471-1464G>A | Intron (SNP) | VAF 18/60 reads (30%) | catalogued as COSV58360613; called by muse, mutect2, varscan2
